Surgical pathology report (de-identified scan), TCGA case TCGA-86-8073, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8073-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Case ID	OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path Report
LUNG TISSUE CHECKLIST
Specimen type: Lobectomy
Tumor site: Lung
Tumor size: 4 x 4 x 3 cm
Histologic type: Bronchiolo-alveolar adenocarcinoma
Histologic grade: Moderately differentiated
Tumor extent: Not specified
Other tumor nodules: Not specified
Lymph nodes: Not specified
Lymphatic invasion: Not specified
Venous invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

Laterality
Left-upper

Excision date

Source: NCI Genomic Data Commons file fc35d0ed-5789-4f7f-923c-d709ee9f040e (TCGA-86-8073.2AE8592B-AA83-476A-B77F-DC53E8EB802B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).